Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A72S, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A72S-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

ICD-3

Carcinoma, renal cell
chromophobe type 8217/3

Site O Kidney NOS
C64.9

W 8/9/13

Diagnosis:

A: Kidney, left, laparoscopic nephrectomy

Tumor histologic type/subtype: Renal cell carcinoma, chromophobe type

Sarcomatoid features: not identified

Histologic grade: 2 (of 4, Fuhrman classification)

Tumor size: 5.5 cm diameter

Tumor focality: unifocal

Extent of invasion:

Extra-capsular invasion into perirenal adipose tissue: not involved

Renal sinus: not involved

Major veins: not involved

Ureter: not involved

Venous: not involved

Lymphatic: not involved

Surgical margins:

Perinephric adipose tissue margin: negative

Renal vein: negative

Ureter: negative

Adrenal gland: not received

Lymph nodes: not received

AJCC Stage (kidney): pT1b pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old female with renal neoplasm.

Gross Description:

Specimen A:

[page 2 of 3]
Specimen fixation: Fresh, and later placed in formalin

Type of specimen: Left laparoscopic nephrectomy

Side of specimen: Left

Size and weight of specimen: Weight 425 gram, 16.0 x 8.5 x 5.5 cm

Orientation: The perinephric fat is inked blue

Presence/absence of adrenal gland: Absent

Tumor site: Renal cortex, mid pole

Tumor description: The tumor is tan/pink, soft with punctate hemorrhage and a 1.5 x 1.4 cm central area, which is yellow soft and liquified. The tumor appears well-circumscribed, with an area suspicious for extracapsular extension.

Tumor size: 5.5 x 4.7 x 4.2 cm

Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: A foci where the mass appears to extend through the renal capsule.

Extent of invasion:

Perirenal adipose tissue: May involve

Gerota' s fascia: Does not involve

Renal vein: Does not involve

Ureter: Does not involve

Renal Sinus: Does not involve

Pelvicaliceal: Does not involve

Adrenal: N/A

Other organs: N.A

Surgical margins:

[page 3 of 3]
Perirenal adipose tissue: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: Within the inferior pole there is a 0.4 cm in greatest dimension smooth walled cyst. The remainder of the kidney parenchyma is tan/red with a distinct cortical medullary junction.

Hilar lymph nodes: None

Other significant findings:

Tissue submitted for normal is submitted to Yes, tumor and

Digital picture: No

Block Summary:

A1 - Ureteral vein and artery margins, en face

A2-A3 - Mass with respect to capsule and perinephric fat, perpendicular

A4 - Mass with respect to sinus fat

A5 - Mass with respect to capsule and perinephric fat

A6 - Uninvolved kidney parenchyma to include cyst

Tissue remains in formalin.

Light Microscopy:

Light microscopic examination is performed by Dr.

Sections of the renal neoplasm show a discrete encapsulated population of dyscohesive cells with perinuclear cytoplasmic clearing and prominent plasma membranes. Zones of fat necrosis are noted. By H & E alone, the differential diagnosis includes chromophobe carcinoma and granular cell/conventional renal cell carcinoma, less likely oncocytoma. Immunostains were performed to clarify lineage, and show diffuse reactivity for CK7 and colloidal iron, subset reactivity for RCC and c-Kit, and no reactivity for vimentin. This immunophenotype supports chromophobe carcinoma, makes conventional RCC unlikely, and excludes oncocytoma. Dr. concurs.

Source: NCI Genomic Data Commons file 797e7a8d-5ed5-4ebc-aac5-5b93efaf77a4 (TCGA-UW-A72S.933DE352-E2B3-4C8C-9828-EF549B971814.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).